Somatic mutation profile of tumor specimen 0DAF1W from CCDI case PBBIMV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,393 days).
Specimen 0DAF1W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 332d869f-9b32-4b10-bc99-f9e563ea41e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAF1G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7cdbb2d-5ed5-4069-92e6-5bd7483c1add

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Intron 3, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 151/375 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, varscan2
- CREBBP | c.678C>G p.Y226* | Nonsense Mutation (SNP) | VAF 76/165 reads (46%) | catalogued as COSV99270011; called by muse, mutect2, varscan2
- DDX3X | c.1589G>A p.R530H (on ENST00000399959; = p.R531H on NM_001356.5) | Missense Mutation (SNP) | VAF 82/482 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1555954275, COSV67863886; ClinVar: other; called by muse, varscan2
- EGR3 | c.1138G>C p.A380P | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.708); catalogued as COSV100416158; called by muse, mutect2, varscan2
- FAT3 | c.12478G>A p.V4160M | Missense Mutation (SNP) | VAF 199/446 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs1371147047; called by muse, mutect2, varscan2
- OR10R2 | c.482G>T p.C161F | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1414239581, COSV63769288; called by muse, mutect2
- SFMBT2 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs145593608; called by muse, mutect2
- SPTA1 | c.3448C>A p.L1150I | Missense Mutation (SNP) | VAF 56/644 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.225); catalogued as COSV100934595; called by muse, mutect2
- TPRX1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 124/351 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.865); catalogued as COSV59116247, COSV59117303; called by muse, mutect2, varscan2
- AL662899.2 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 191/290 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- DDX3X | c.692C>A p.A231E (on ENST00000399959; = p.A232E on NM_001356.5) | Missense Mutation (SNP) | VAF 60/541 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.8505_8506insAGCG p.R2836Sfs*10 | Frame Shift Ins (INS) | VAF 124/324 reads (38%) | called by mutect2, varscan2
- MTIF2 | c.920A>T p.Y307F | Missense Mutation (SNP) | VAF 163/556 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 25/545 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RASIP1 | c.542A>C p.E181A | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- USP17L10 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 130/188 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 42/618 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- JCAD | c.3537C>T p.D1179= | Silent (SNP) | VAF 113/353 reads (32%) | catalogued as rs768287686, COSV64759600; called by muse, mutect2, varscan2
- PCDHB16 | c.2253C>T p.Y751= | Silent (SNP) | VAF 15/356 reads (4%) | catalogued as rs564789192, COSV53369981; called by muse, mutect2
- USP17L10 | c.1482G>A p.P494= | Silent (SNP) | VAF 241/370 reads (65%) | called by muse, mutect2, varscan2
- ZFP69 | c.99G>A p.E33= | Silent (SNP) | VAF 22/318 reads (7%) | catalogued as COSV65529499; called by muse, mutect2
- ERMAP | c.86-9T>C | Intron (SNP) | VAF 49/113 reads (43%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- NPHP1 | c.1927-30A>T | Intron (SNP) | VAF 8/94 reads (9%) | called by mutect2, varscan2
- OR52Z1 | n.377G>A | RNA (SNP) | VAF 190/457 reads (42%) | catalogued as rs777998760; called by muse, mutect2, varscan2
